Somatic mutation profile of tumor specimen TCGA-B5-A11W-01A (aliquot TCGA-B5-A11W-01A-12D-A122-09) from TCGA case TCGA-B5-A11W, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G2; Age at diagnosis: 61.2 years (22,365 days).
Specimen TCGA-B5-A11W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0ff01af8-5fc3-4267-adfa-43e16511d90c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B5-A11W-10A (Blood Derived Normal), aliquot TCGA-B5-A11W-10A-01D-A122-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ea91a8b7-251a-4c18-b96e-5dad3827855b

The open-access MAF lists 76 somatic variants for this specimen: 62 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 51, Silent 14, Nonsense Mutation 6, Frame Shift Ins 2, Frame Shift Del 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ING1 | c.1015C>T p.R339* | Nonsense Mutation (SNP) | VAF 18/50 reads (36%) | hotspot (GDC flag); catalogued as COSV58167363; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 288/463 reads (62%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- RHEB | c.103T>A p.Y35N | Missense Mutation (SNP) | VAF 139/309 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519949, COSV51263142, COSV51264088; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCC1 | c.175C>T p.R59* | Nonsense Mutation (SNP) | VAF 197/472 reads (42%) | catalogued as rs768037858, COSV60695788; called by muse, mutect2, varscan2
- ARID1A | c.2248C>T p.R750* | Nonsense Mutation (SNP) | VAF 45/97 reads (46%) | catalogued as COSV100250607, COSV61371935; called by muse, mutect2, varscan2
- BMP15 | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 43/80 reads (54%) | SIFT tolerated (0.38); PolyPhen benign (0.019); catalogued as rs782187019, COSV53142289; called by muse, mutect2, varscan2
- CACNA1B | c.5402C>T p.T1801M | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as rs1208520621, COSV53152376; called by muse, mutect2, varscan2
- CCDC144A | c.1802C>G p.S601C | Missense Mutation (SNP) | VAF 125/365 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV60702553; called by muse, mutect2, varscan2
- CFAP61 | c.2677G>A p.A893T | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.186); catalogued as COSV55646813; called by muse, mutect2, varscan2
- CHD8 | c.3628C>T p.R1210W (on ENST00000646647 / NM_001170629.2; = p.R931W on NM_020920.4) | Missense Mutation (SNP) | VAF 69/154 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757278444, COSV67873025; called by muse, mutect2, varscan2
- COX7B2 | c.221C>T p.T74I | Missense Mutation (SNP) | VAF 79/195 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.247); catalogued as rs538139494, COSV57224055; called by muse, mutect2, varscan2
- DEFB126 | c.76A>G p.K26E | Missense Mutation (SNP) | VAF 98/245 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as COSV66695129; called by muse, mutect2, varscan2
- DNER | c.1540T>A p.C514S | Missense Mutation (SNP) | VAF 77/188 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs765620955, COSV59178422; called by muse, mutect2, varscan2
- DSCAM | c.1553G>T p.G518V | Missense Mutation (SNP) | VAF 117/275 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68038005; called by muse, mutect2, varscan2
- EHMT1 | c.3543C>T p.D1181= | Splice Region (SNP) | VAF 15/36 reads (42%) | catalogued as rs1261628877, COSV66044706; called by muse, mutect2, varscan2
- ETV2 | c.876C>A p.Y292* | Nonsense Mutation (SNP) | VAF 15/31 reads (48%) | catalogued as COSV55838677; called by muse, mutect2, varscan2
- F11 | c.1328G>A p.R443H | Missense Mutation (SNP) | VAF 174/404 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.143); catalogued as rs373212439; called by muse, mutect2, varscan2
- FAM168A | c.718G>A p.V240M (on ENST00000064778 / NM_001286050.2; = p.V231M on NM_015159.3) | Missense Mutation (SNP) | VAF 99/211 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.987); catalogued as rs752569750, COSV50360466; called by muse, mutect2, varscan2
- GPATCH8 | c.2950C>T p.R984W | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as rs763823154, COSV59193145; called by muse, mutect2, varscan2
- GPER1 | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs763449832, COSV52470998; called by muse, mutect2, varscan2
- HSPA14 | c.1375G>T p.A459S | Missense Mutation (SNP) | VAF 56/123 reads (46%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.49); catalogued as COSV65685410; called by muse, mutect2, varscan2
- HSPA14 | c.1376C>T p.A459V | Missense Mutation (SNP) | VAF 55/122 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs944591423, COSV65685416; called by muse, mutect2, varscan2
- IGFBP7 | c.520G>A p.G174S | Missense Mutation (SNP) | VAF 44/92 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55277475; called by muse, mutect2, varscan2
- IMP4 | c.415G>A p.V139I | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.034); catalogued as rs763213766, COSV52093022; called by muse, mutect2, varscan2
- KCNB2 | c.919C>T p.R307C | Missense Mutation (SNP) | VAF 45/129 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867030236, COSV73049898; called by muse, mutect2, varscan2
- KIF18B | c.334G>A p.G112R | Missense Mutation (SNP) | VAF 58/119 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs551380420, COSV59274084; called by muse, mutect2, varscan2
- KLHL25 | c.118C>T p.R40C | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772155808, COSV61994755; called by muse, mutect2, varscan2
- LMTK2 | c.3539C>T p.P1180L | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs140934676; called by muse, mutect2, varscan2
- MOGAT3 | c.874G>A p.G292S | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56177496, COSV99033926; called by muse, mutect2, varscan2
- MRTFB | c.1705G>T p.E569* | Nonsense Mutation (SNP) | VAF 44/98 reads (45%) | catalogued as COSV57962468; called by muse, mutect2, varscan2
- MYO18B | c.757C>A p.L253M | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.299); catalogued as COSV59151212; called by muse, mutect2, varscan2
- MYO3A | c.3082C>A p.L1028I | Missense Mutation (SNP) | VAF 60/159 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.872); catalogued as COSV56326344; called by muse, mutect2, varscan2
- NF1 | c.2294G>T p.R765L | Missense Mutation (SNP) | VAF 47/126 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.132); catalogued as rs199474777, CM142754, COSV62201563, COSV62224447; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NF1 | c.4851A>C p.Q1617H (on ENST00000358273 / NM_001042492.3; = p.Q1596H on NM_000267.3) | Missense Mutation (SNP) | VAF 60/148 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.175); catalogued as COSV55987162, COSV99907569; called by muse, mutect2, varscan2
- OR4D2 | c.833T>C p.M278T | Missense Mutation (SNP) | VAF 56/117 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.369); catalogued as COSV73459895; called by muse, mutect2, varscan2
- PIK3R1 | c.1724dup p.T576Dfs*26 (on ENST00000521381 / NM_181523.3; = p.T306Dfs*26 on NM_181504.4) | Frame Shift Ins (INS) | VAF 142/366 reads (39%) | catalogued as COSV99073797; called by mutect2, pindel, varscan2
- PKD1 | c.2824G>A p.E942K | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.024); catalogued as rs1345631696, COSV99237606; called by muse, mutect2
- POLR2F | c.353G>A p.W118* | Nonsense Mutation (SNP) | VAF 39/87 reads (45%) | catalogued as COSV62807618; called by muse, mutect2, varscan2
- PRRC2B | c.1060A>C p.N354H | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV61944076; called by muse, mutect2, varscan2
- RERE | c.1946G>A p.R649H | Missense Mutation (SNP) | VAF 69/181 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs777899098, COSV61952448; called by muse, mutect2, varscan2
- RNF165 | c.442C>G p.L148V | Missense Mutation (SNP) | VAF 47/106 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.125); catalogued as COSV53978715; called by muse, mutect2, varscan2
- SAMD7 | c.136G>A p.V46I | Missense Mutation (SNP) | VAF 93/239 reads (39%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as rs138587022; called by muse, mutect2, varscan2
- SELENBP1 | c.340C>T p.R114W | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs191782924, COSV64374310; called by muse, mutect2, varscan2
- SFXN2 | c.626G>A p.R209K | Missense Mutation (SNP) | VAF 59/131 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV64013387; called by muse, mutect2, varscan2
- SKOR1 | c.764C>T p.S255L | Missense Mutation (SNP) | VAF 5/99 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.15); catalogued as COSV100408254; called by muse, mutect2
- ST6GALNAC4 | c.325G>A p.V109M | Missense Mutation (SNP) | VAF 8/21 reads (38%) | PolyPhen benign (0.037); catalogued as rs747112947, COSV59130803; called by muse, mutect2, varscan2
- STK40 | c.143G>C p.S48T | Missense Mutation (SNP) | VAF 90/223 reads (40%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.908); catalogued as COSV63737213; called by muse, mutect2, varscan2
- STXBP6 | c.11A>G p.K4R | Missense Mutation (SNP) | VAF 59/151 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.16); catalogued as rs1262945978, COSV60598934; called by muse, mutect2, varscan2
- TLR2 | c.1538C>T p.T513M | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs145961078; called by muse, mutect2, varscan2
- TMEM242 | c.241C>G p.R81G | Missense Mutation (SNP) | VAF 72/194 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100900889, COSV65654069; called by muse, mutect2
- TNIK | c.1429C>T p.R477C | Missense Mutation (SNP) | VAF 132/339 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs774723546, COSV52698702; called by muse, varscan2
- TRIP4 | c.1091C>T p.P364L | Missense Mutation (SNP) | VAF 78/186 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs770397345, COSV56033851; called by muse, mutect2, varscan2
- ZFHX4 | c.4924G>T p.V1642F | Missense Mutation (SNP) | VAF 51/110 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.172); catalogued as COSV50624827, COSV51499969; called by muse, mutect2, varscan2
- ZNF133 | c.1128C>G p.H376Q (on ENST00000316358 / NM_001352454.2; = p.H375Q on NM_003434.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60368332; called by muse, mutect2, varscan2
- ZNF415 | c.1274C>T p.S425L | Missense Mutation (SNP) | VAF 78/197 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as COSV54701369; called by muse, mutect2, varscan2
- ZNF644 | c.1747T>A p.S583T | Missense Mutation (SNP) | VAF 63/148 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as COSV100494349; called by muse, mutect2, varscan2
- ZNF648 | c.821G>C p.G274A | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs754881990, COSV60569527; called by muse, mutect2, varscan2
- ARID1A | c.4220del p.P1407Qfs*74 | Frame Shift Del (DEL) | VAF 8/23 reads (35%) | called by mutect2, pindel
- FCGBP | c.7954C>A p.L2652M | Missense Mutation (SNP) | VAF 49/240 reads (20%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.954); called by muse, mutect2
- PIK3R1 | c.1021dup p.X341_splice (on ENST00000521381 / NM_181523.3; = p.X71_splice on NM_181504.4) | Splice Site (INS) | VAF 96/288 reads (33%) | called by mutect2, pindel, varscan2
- PTEN | c.1019dup p.N340Kfs*3 | Frame Shift Ins (INS) | VAF 72/114 reads (63%) | called by mutect2, pindel, varscan2
- UBE2NL | c.323C>T p.S108L | Missense Mutation (SNP) | VAF 155/371 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- C8orf33 | c.532C>T p.L178= | Silent (SNP) | VAF 49/91 reads (54%) | catalogued as COSV58896197; called by muse, mutect2, varscan2
- CGN | c.1977C>T p.D659= | Silent (SNP) | VAF 14/29 reads (48%) | catalogued as COSV54974389; called by muse, mutect2, varscan2
- FRS3 | c.1110G>T p.L370= | Silent (SNP) | VAF 12/22 reads (55%) | catalogued as COSV52487264; called by muse, varscan2
- IGF2R | c.5646G>A p.A1882= | Silent (SNP) | VAF 106/242 reads (44%) | catalogued as rs371201097; called by muse, mutect2, varscan2
- LPA | c.1044G>A p.P348= | Silent (SNP) | VAF 16/234 reads (7%) | catalogued as rs773580636; called by muse, varscan2
- MIB2 | c.1986G>A p.V662= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as COSV61543584; called by muse, mutect2, varscan2
- NUP153 | c.2685G>A p.S895= | Silent (SNP) | VAF 39/111 reads (35%) | catalogued as rs749852957, COSV50447294; called by muse, mutect2, varscan2
- OR10H2 | c.270C>T p.R90= | Silent (SNP) | VAF 102/361 reads (28%) | catalogued as COSV100008685; called by muse, mutect2
- PPP1R9B | c.2121G>A p.A707= | Silent (SNP) | VAF 70/164 reads (43%) | catalogued as rs747668995, COSV100380662; called by muse, mutect2, varscan2
- RNF123 | c.1593T>C p.F531= | Silent (SNP) | VAF 28/68 reads (41%) | catalogued as COSV59693232; called by muse, mutect2, varscan2
- TRRAP | c.5883C>G p.V1961= (on ENST00000359863 / NM_001244580.1; = p.V1943= on NM_003496.3) | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as COSV62855964; called by muse, mutect2, varscan2
- UBIAD1 | c.225C>T p.S75= | Silent (SNP) | VAF 53/114 reads (46%) | catalogued as rs777266523, COSV65148301; called by muse, mutect2, varscan2
- USH1G | c.633G>A p.R211= | Silent (SNP) | VAF 16/34 reads (47%) | catalogued as COSV58884035; called by muse, mutect2, varscan2
- WHAMM | c.876C>T p.V292= | Silent (SNP) | VAF 90/228 reads (39%) | catalogued as rs1193276142, COSV54500196; ClinVar: likely benign; called by muse, mutect2, varscan2
